Gene-level copy-number profile of tumor specimen TCGA-HU-A4GY-01A from TCGA case TCGA-HU-A4GY, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 77.0 years (28,113 days).
Specimen TCGA-HU-A4GY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.948e5605-6d28-4b20-8d66-9fcbee399cf0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-A4GY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4da6118d-735d-406f-b6fc-200786edf397

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,946; copy number 2: 45,125; copy number 3: 7,566; copy number 7: 7; copy number 8: 2; copy number 9: 36; copy number 31: 11; copy number 32: 19; copy number 33: 72; copy number 34: 4; copy number 36: 1; copy number 44: 3; copy number 49: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-A4GY-01A-21D-A24C-01): tumor purity 0.21, ploidy 2.31, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 176 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:120,354,701–122,254,545, 28 genes, copy number 49 (within-gene range 2–49): RPL21P16, AC073587.1, PLPP4, LINC01561, AC023282.1, WDR11-AS1, AL391425.1, WDR11, AC010998.2, AC010998.1, AC010998.3, RPL19P16, LINC01153, RN7SKP167, FGFR2, AC009988.1, RPS15AP5, AC025947.1, ATE1, Y_RNA, ATE1-AS1, AL731566.1, AL731566.3, NSMCE4A, AL731566.2, TACC2, AC063960.1, AC063960.2.
- chr10:130,962,588–131,311,721, 3 genes, copy number 44: MIR378C, TCERG1L, TCERG1L-AS1.
- chr11:68,612,899–70,021,059, 38 genes, copy number 8–9: AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1.
- chr15:22,838,644–22,981,063, 2 genes, copy number 34 (within-gene range 2–34): NIPA2, CYFIP1.
- chr15:89,243,945–90,717,141, 72 genes, copy number 33 (within-gene range 2–33) (broad region; genes not listed).
- chr15:91,742,841–92,501,117, 11 genes, copy number 31: THRAP3P2, SLCO3A1, AC116903.2, AC116903.1, DUXAP6, NPM1P5, ST8SIA2, AC090985.1, ENO1P2, AC090985.2, C15orf32.
- chr15:92,819,540–94,070,898, 19 genes, copy number 32 (within-gene range 2–32): CHASERR, AC013394.1, CHD2, MIR3175, RGMA, YBX2P2, AC108457.1, AC091078.1, AC112693.1, AC112693.2, AC091078.2, SEPHS1P2, AC110023.1, LINC01579, AC103996.1, LINC02207, AC103996.3, AC103996.2, LINC01580.
- chr15:95,463,587–95,493,843, 1 gene, copy number 36: AC027013.1.
- chr15:98,282,075–98,320,237, 2 genes, copy number 34: AC015722.1, AC015722.2.

Autosomal genes at a single copy (total copy number 1): 6,918. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
